Gene-level copy-number profile of tumor specimen TCGA-61-1907-01A from TCGA case TCGA-61-1907, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.5 years (23,204 days).
Specimen TCGA-61-1907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ca3115ed-9f4b-4831-aa71-7321a71295d2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1907-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c0a3d2e7-35ad-47d8-827d-cd64f981d2d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,465; copy number 2: 19,522; copy number 3: 14,283; copy number 4: 13,481; copy number 5: 6,438; copy number 6: 2,873; copy number 7: 292; copy number 8: 871; copy number 9: 257; copy number 10: 225; copy number 11: 10; copy number 12: 9; copy number 14: 81.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1907-01A-01D-0577-01): tumor purity 0.76, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:32,384,660–32,432,954, 4 genes: IFIT1P1, N4BP2L1, AL137247.1, AL137247.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11,056 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,119,429–56,996,757, 789 genes, copy number 6 (broad region; genes not listed).
- chr1:57,386,576–57,387,450, 1 gene, copy number 6: AL390243.1.
- chr1:118,883,046–121,580,524, 78 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:151,612,006–151,699,091, 1 gene, copy number 5 (within-gene range 3–5): SNX27.
- chr1:151,700,058–152,445,456, 42 genes, copy number 5: CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN, FLG-AS1, AL589986.2, HRNR, FLG, FLG2, HMGN3P1, CRNN.
- chr2:75,046,463–80,648,861, 59 genes, copy number 6 (within-gene range 4–6): TACR1, MIR5000, AC007681.1, GAPDHP57, EVA1A, AC007099.2, AC007099.3, AC007099.1, AC005034.1, U3, MRPL19, SUPT4H1P1, GCFC2, AC005034.3, AC005034.5, AC005034.2, AC005034.6, AC005034.4, AC110614.1, SUCLA2P2, AC073091.1, AC073091.2, PNPP1, USP21P2, RN7SKP203, RN7SKP164, AC068616.2, AC068616.3, AC068616.1, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1, AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080.
- chr2:114,442,299–119,438,504, 40 genes, copy number 5 (within-gene range 3–5): DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1, AC009312.1, DDX18, AC009404.1, HTR5BP, CCDC93, AC009303.1, AC009303.2, AC009303.3, AC009303.4, RN7SL111P, INSIG2, THORLNC, LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37.
- chr2:152,284,350–197,676,045, 625 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:124,723,788–140,902,651, 352 genes, copy number 5 (broad region; genes not listed).
- chr3:164,001,606–187,449,450, 405 genes, copy number 6–7 (broad region; genes not listed).
- chr4:49,096–16,512,187, 377 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:3,045,384–5,260,950, 61 genes, copy number 6 (broad region; genes not listed).
- chr6:5,291,030–5,291,388, 1 gene, copy number 6: AL121978.1.
- chr6:63,719,980–65,707,226, 1 gene, copy number 5 (within-gene range 4–5): EYS.
- chr6:64,631,205–67,210,480, 9 genes, copy number 5: HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1.
- chr7:17,940,503–44,490,658, 493 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:63,011,463–68,319,676, 207 genes, copy number 8–14 (broad region; genes not listed).
- chr7:112,206,695–113,146,330, 21 genes, copy number 7: ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30.
- chr7:122,849,746–123,230,741, 5 genes, copy number 7: AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1.
- chr8:20,079,114–20,934,837, 12 genes, copy number 5: AC100802.1, RPL30P9, SLC18A1, ATP6V1B2, RNU6-892P, LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1, AC022559.1, AC018541.1, TMEM97P2.
- chr8:64,331,927–145,066,685, 1,267 genes, copy number 5–10 (broad region; genes not listed).
- chr9:27,948,078–73,170,393, 639 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr10:111,787,233–114,996,593, 57 genes, copy number 7 (within-gene range 4–7): AL136119.1, GPAM, TECTB, MIR6715B, MIR6715A, GUCY2GP, ACSL5, AL157786.1, ZDHHC6, VTI1A, AC022018.1, MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1, AFAP1L2, RN7SL384P, AL133384.2, ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626.
- chr10:115,123,482–115,218,819, 1 gene, copy number 7: AC016042.1.
- chr11:64,726,911–135,075,908, 1,669 genes, copy number 5–8 (broad region; genes not listed).
- chr12:66,767–63,823,895, 1,632 genes, copy number 5–12 (broad region; genes not listed).
- chr12:63,871,739–63,879,474, 2 genes, copy number 6: RPL36AP41, AC079866.2.
- chr14:104,653,548–106,875,071, 245 genes, copy number 6 (broad region; genes not listed).
- chr15:43,106,225–43,185,779, 1 gene, copy number 5 (within-gene range 2–5): AC068724.3.
- chr15:43,123,279–101,933,350, 1,480 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).
- chr21:36,005,338–39,929,397, 108 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,465. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
